TCGA case TCGA-08-0357 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/548c3d4c-7993-40dc-bd02-5bb304188d28

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 49 years; Vital status: Dead; Days to death: 1,143 days (3.1 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 49.7 years (18,144 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 71 days; Treatment dose: 6,005 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 71 days; Number of cycles: 1; Treatment dose: 75 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 93 days; Days to treatment end: 136 days; Number of cycles: 1; Treatment dose: 75 mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Thalidomide; Treatment intent type: Adjuvant; Days to treatment start: 93 days; Days to treatment end: 136 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Cintredekin Besudotox; Initial disease status: Progressive Disease; Days to treatment start: 184 days; Days to treatment end: 188 days; Treatment dose: 36 mg.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 471 days (1.3 years); Days to treatment end: 688 days (1.9 years); Treatment dose: 475 mg.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 471 days (1.3 years); Days to treatment end: 688 days (1.9 years); Treatment dose: 775 mg; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Hydroxyurea; Initial disease status: Progressive Disease; Days to treatment start: 689 days (1.9 years); Days to treatment end: 733 days (2.0 years); Number of cycles: 1; Treatment dose: 1,000 mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Imatinib Mesylate; Initial disease status: Progressive Disease; Days to treatment start: 689 days (1.9 years); Days to treatment end: 733 days (2.0 years); Treatment dose: 1,000 mg/day.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Initial disease status: Progressive Disease; Days to treatment start: 736 days (2.0 years); Days to treatment end: 860 days (2.4 years); Number of cycles: 3; Treatment dose: 110 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Recombinant Interferon Alfa; Initial disease status: Progressive Disease; Days to treatment start: 736 days (2.0 years); Days to treatment end: 860 days (2.4 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sirolimus; Initial disease status: Progressive Disease; Days to treatment start: 736 days (2.0 years); Days to treatment end: 860 days (2.4 years); Treatment dose: 5 mg/day.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 875 days (2.4 years); Days to treatment end: 985 days (2.7 years); Number of cycles: 3; Treatment dose: 100 mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,007 days (2.8 years); Days to treatment end: 1,084 days (3.0 years); Treatment dose: 100 mg.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib; Initial disease status: Progressive Disease; Days to treatment start: 1,007 days (2.8 years); Days to treatment end: 1,084 days (3.0 years); Treatment dose: 400 mg/day.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Progressive Disease; Days to treatment start: 1,097 days (3.0 years); Days to treatment end: 1,112 days (3.0 years); Treatment dose: 100 mg/day; Treatment outcome: Treatment Ongoing.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 50.1 years (18,299 days); Days to diagnosis: 155 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 180 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 155 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 155 days.
- Days to follow up: 1,084 days (3.0 years); Disease response: With Tumor.
- Days to follow up: 1,143 days (3.1 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 80; Timepoint: Other.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-08-0357-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-08-0357-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0.
  Slide TCGA-08-0357-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-08-0357-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-08-0357-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Hyrdroxyurea; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Rapamycin; Therapy regimen: Progression.
- Drug treatment 3: Pharmaceutical therapy drug name: Ccnu; Therapy regimen: Progression.
- Drug treatment 5: Pharmaceutical therapy drug name: Gleevac; Therapy regimen: Progression.
- Drug treatment 6: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 7: Pharmaceutical therapy drug name: Interferon Alpha; Therapy regimen: Progression.
- Drug treatment 8: Pharmaceutical therapy drug name: IL-13 Pseudomonas exotoxin; Therapy regimen: Progression.
- Drug treatment 10: Pharmaceutical therapy drug name: Cytoxan; Therapy regimen: Progression.
- Drug treatment 11: Pharmaceutical therapy drug name: VP-16; Therapy regimen: Progression.
- Drug treatment 14: Pharmaceutical therapy drug name: Tarveca; Therapy regimen: Progression.
- Drug treatment 15: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,143 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,143 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 155 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-08-0357-01): tumor purity 0.75, ploidy 2.01, whole-genome doublings 0 (call status: legacy_call).
